Somatic mutation profile of tumor specimen MP2PRT-PATTVG-TMP1-A (aliquot MP2PRT-PATTVG-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATTVG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,863 days).
Specimen MP2PRT-PATTVG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f441a006-d048-4cd9-964d-8c0a1a5ba665.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATTVG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATTVG-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c42e07e-73fb-4b9b-bf16-0bb58df17fc1

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 6 silent.
By variant classification: Silent 6, Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 132/351 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HTR5A | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 146/334 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as rs910479674, COSV55280189; called by muse, mutect2, varscan2
- KIAA2026 | c.4973C>G p.A1658G | Missense Mutation (SNP) | VAF 27/379 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.35); catalogued as rs780350596; called by muse, mutect2
- ARHGAP36 | c.148G>C p.V50L | Missense Mutation (SNP) | VAF 293/624 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FZD3 | c.610T>G p.Y204D | Missense Mutation (SNP) | VAF 160/346 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- KIF6 | c.593C>A p.A198D | Missense Mutation (SNP) | VAF 90/396 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP8B3 | c.1668C>T p.N556= | Silent (SNP) | VAF 177/452 reads (39%) | catalogued as rs369043090; called by muse, mutect2, varscan2
- BRINP3 | c.1437C>T p.A479= | Silent (SNP) | VAF 140/321 reads (44%) | catalogued as rs540252549, COSV100818902, COSV66533549; called by muse, mutect2, varscan2
- MAP2 | c.801C>T p.I267= | Silent (SNP) | VAF 143/422 reads (34%) | catalogued as rs775528286, COSV52288621; called by muse, mutect2, varscan2
- NOMO1 | c.1596G>A p.R532= | Silent (SNP) | VAF 66/293 reads (23%) | called by muse, mutect2, varscan2
- SHISA6 | c.867G>A p.S289= (on ENST00000409168 / NM_001173461.1; = p.S340= on NM_207386.4) | Silent (SNP) | VAF 221/704 reads (31%) | catalogued as rs377388134; called by muse, mutect2, varscan2
- STK26 | c.1104C>T p.D368= | Silent (SNP) | VAF 31/325 reads (10%) | catalogued as rs761659579, COSV100049472, COSV53745359; called by muse, mutect2
